Somatic mutation profile of tumor specimen MMRF_2763_1_BM_CD138pos (aliquot MMRF_2763_1_BM_CD138pos_T1_KHS5U_L15715) from MMRF case MMRF_2763, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.4 years (23,540 days).
Specimen MMRF_2763_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 783b4d5f-40cf-4a8b-8496-a0513990369b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2763_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2763_1_PB_WBC_C3_KHS5U_L15759; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4088d0b5-a916-4956-b68e-2d1c8572c95b

The open-access MAF lists 136 somatic variants for this specimen: 48 protein-altering or splice-affecting, 22 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 35, Silent 22, Intron 13, 5'UTR 8, 3'Flank 4, 5'Flank 3, Nonsense Mutation 3, RNA 3, Splice Site 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 38/92 reads (41%) | catalogued as rs137852991, CM003583, COSV55395411; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 94/324 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.2836G>A p.V946M | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs768146819; called by muse, mutect2, varscan2
- BAHCC1 | c.3509G>A p.R1170Q | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs1555654747; called by muse, mutect2
- CHRM1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 34/427 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1382129041, COSV61007475; called by muse, mutect2
- CHRNA2 | c.1190T>A p.L397H | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.088); catalogued as rs1346642868; called by muse, mutect2
- DIDO1 | c.6512G>A p.R2171H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1347077259, COSV56620909; called by muse, mutect2, varscan2
- EIF2AK3 | c.1952T>G p.I651S | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM097418; called by muse, mutect2
- ENC1 | c.397C>G p.R133G | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV56629300; called by muse, mutect2
- H1-4 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56799905, COSV56803909; called by muse, mutect2, varscan2
- HCAR1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs769398132; called by muse, mutect2, varscan2
- IGHV2-70 | c.343T>A p.Y115N | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761286005; called by muse, varscan2
- IGHV2-70 | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs578104643; called by muse, varscan2
- IGHV2-70 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs72690597; called by muse, varscan2
- IRX1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs976102129; called by muse, mutect2
- KRTAP24-1 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs758473615, COSV61089233, COSV61089290; called by muse, mutect2
- KSR2 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs749908572; called by muse, mutect2, varscan2
- PNPLA6 | c.3623G>A p.C1208Y (on ENST00000414982 / NM_001166111.2; = p.C1160Y on NM_006702.5) | Missense Mutation (SNP) | VAF 118/458 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55376621; called by muse, mutect2, varscan2
- SLC25A13 | c.2007G>T p.K669N | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.01); catalogued as COSV99672918; called by muse, mutect2, varscan2
- SPHK1 | c.887G>A p.R296H (on ENST00000392496 / NM_001355139.2; = p.R310H on NM_021972.4) | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs144131867; called by muse, mutect2, varscan2
- TTN | c.78193G>A p.E26065K (on ENST00000591111; = p.E18641K on NM_003319.4) | Missense Mutation (SNP) | VAF 134/285 reads (47%) | PolyPhen benign (0.046); catalogued as rs72648217, COSV59954756; called by muse, mutect2, varscan2
- USP15 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 137/322 reads (43%) | catalogued as COSV54800887; called by muse, mutect2, varscan2
- WSB2 | c.660G>A p.S220= | Splice Region (SNP) | VAF 14/35 reads (40%) | catalogued as rs1188127984, COSV59573880; called by muse, mutect2, varscan2
- ADAMTSL4 | c.608C>G p.P203R | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADGRL2 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 114/293 reads (39%) | called by muse, mutect2, varscan2
- ANTXR2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- ASB3 | c.1439G>C p.R480P | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); called by muse, mutect2
- BPTF | c.595A>T p.T199S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- CLEC11A | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CST9 | c.458T>G p.I153S | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- DCN | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 104/248 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA5 | c.2508+1G>T p.X836_splice | Splice Site (SNP) | VAF 68/211 reads (32%) | called by muse, mutect2, varscan2
- IGHD1-1 | c.5C>G p.T2R | Missense Mutation (SNP) | VAF 8/11 reads (73%) | PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- IGHV2-70D | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); called by muse, varscan2
- KCNK7 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRIQ1 | c.472T>G p.F158V | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- MAP3K10 | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PRKCQ | c.1550A>T p.H517L | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAI14 | c.1399G>T p.V467L | Missense Mutation (SNP) | VAF 23/312 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- RGS12 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3RF2 | c.177C>A p.N59K | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- SYNM | c.3697_3699del p.E1233del | In Frame Del (DEL) | VAF 144/254 reads (57%) | called by mutect2, pindel, varscan2
- TM6SF2 | c.200-2A>T p.X67_splice | Splice Site (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- TRAIP | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBJ2-4 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 95/170 reads (56%) | called by muse, mutect2, varscan2
- TTN | c.68963C>T p.T22988I (on ENST00000591111; = p.T15564I on NM_003319.4) | Missense Mutation (SNP) | VAF 22/198 reads (11%) | PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- WDR49 | c.1562A>T p.H521L (on ENST00000308378 / NM_001366158.1; = p.H862L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- WNK3 | c.3735G>C p.Q1245H | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY10 | c.4479C>G p.L1493= | Silent (SNP) | VAF 73/156 reads (47%) | called by muse, mutect2, varscan2
- BAHCC1 | c.951C>T p.S317= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs781992152; called by muse, mutect2, varscan2
- CKAP2 | c.555G>A p.Q185= (on ENST00000378037 / NM_001098525.2; = p.Q184= on NM_018204.5) | Silent (SNP) | VAF 79/144 reads (55%) | called by muse, mutect2, varscan2
- CTSF | c.1443G>A p.A481= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as rs750349901, COSV100074131; called by muse, mutect2, varscan2
- FAT4 | c.3582C>G p.A1194= | Silent (SNP) | VAF 106/214 reads (50%) | called by muse, mutect2, varscan2
- FLNC | c.6990C>T p.G2330= | Silent (SNP) | VAF 14/169 reads (8%) | catalogued as rs113579230, COSV57953015; called by muse, mutect2
- HTT | c.3591G>A p.P1197= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs181975938; called by muse, mutect2, varscan2
- IGHV2-70 | c.150T>G p.T50= | Silent (SNP) | VAF 88/180 reads (49%) | catalogued as rs796173324; called by muse, varscan2
- IGLV3-1 | c.294T>A p.A98= | Silent (SNP) | VAF 272/427 reads (64%) | catalogued as rs546240484; called by muse, varscan2
- ITGAE | c.1440T>G p.A480= | Silent (SNP) | VAF 49/158 reads (31%) | called by muse, mutect2, varscan2
- KCNF1 | c.459C>T p.G153= | Silent (SNP) | VAF 80/200 reads (40%) | catalogued as COSV99705543; called by muse, mutect2
- LCP2 | c.33G>A p.E11= | Silent (SNP) | VAF 22/496 reads (4%) | called by muse, mutect2
- NME8 | c.906T>C p.A302= | Silent (SNP) | VAF 13/149 reads (9%) | called by muse, mutect2
- OR2M5 | c.855G>T p.L285= | Silent (SNP) | VAF 70/331 reads (21%) | called by muse, mutect2, varscan2
- OR3A1 | c.357C>T p.T119= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as rs144174017; called by muse, mutect2, varscan2
- SLC47A1 | c.1347A>G p.Q449= | Silent (SNP) | VAF 68/185 reads (37%) | catalogued as rs755282983; called by muse, mutect2, varscan2
- SULT1E1 | c.492A>G p.G164= | Silent (SNP) | VAF 37/228 reads (16%) | called by muse, mutect2, varscan2
- TPP1 | c.1393A>C p.R465= | Silent (SNP) | VAF 15/188 reads (8%) | called by muse, mutect2
- TRIM7 | c.1224C>T p.G408= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- TTC24 | c.516A>G p.L172= | Silent (SNP) | VAF 66/228 reads (29%) | called by muse, mutect2, varscan2
- ZFYVE1 | c.873C>T p.F291= | Silent (SNP) | VAF 23/157 reads (15%) | catalogued as COSV59609578; called by muse, mutect2, varscan2
- ZNF850 | c.1392A>G p.L464= | Silent (SNP) | VAF 129/451 reads (29%) | called by muse, mutect2, varscan2
- ACOT13 | c.-129C>T | 5'UTR (SNP) | VAF 23/244 reads (9%) | called by muse, mutect2
- ACTN3 | chr11:66546694 G>T | 5'Flank (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- ADPRS | c.*222G>A | 3'UTR (SNP) | VAF 46/150 reads (31%) | catalogued as rs1442745809; called by muse, mutect2, varscan2
- ARHGEF4 | c.*822G>A | 3'UTR (SNP) | VAF 13/138 reads (9%) | catalogued as rs565128923; called by muse, mutect2
- ARIH2 | c.*763C>G | 3'UTR (SNP) | VAF 104/331 reads (31%) | called by muse, mutect2, varscan2
- BLZF1 | c.*27+485T>C | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- BPNT2 | c.*5465T>A | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- BTNL9 | c.*749C>G | 3'UTR (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- C12orf43 | c.*56C>T | 3'UTR (SNP) | VAF 14/223 reads (6%) | called by muse, mutect2
- C1orf115 | c.*2029T>C | 3'UTR (SNP) | VAF 51/124 reads (41%) | called by muse, mutect2, varscan2
- CA14 | c.-45_-44del | 5'UTR (DEL) | VAF 15/58 reads (26%) | called by pindel, varscan2
- CACNA1C | c.3828+487C>A | Intron (SNP) | VAF 87/221 reads (39%) | called by muse, mutect2, varscan2
- CAPZA2 | c.*825T>A | 3'UTR (SNP) | VAF 62/118 reads (53%) | called by muse, mutect2
- CCR6 | c.*2225T>G | 3'UTR (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- CDX4 | c.*204A>C | 3'UTR (SNP) | VAF 33/41 reads (80%) | called by muse, mutect2, varscan2
- CENPH | c.*205G>T | 3'UTR (SNP) | VAF 90/146 reads (62%) | catalogued as rs907724441; called by muse, mutect2
- CFAP91 | c.682+158C>G | Intron (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- CHERP | c.-27C>T | 5'UTR (SNP) | VAF 52/205 reads (25%) | catalogued as rs760443633; called by muse, mutect2, varscan2
- CHFR | chr12:132840665 G>A | 3'Flank (SNP) | VAF 8/244 reads (3%) | catalogued as rs1455110594; called by muse, mutect2
- CNTN6 | chr3:1404114 G>T | 3'Flank (SNP) | VAF 38/134 reads (28%) | called by muse, mutect2, varscan2
- DCLK1 | c.*1341C>T | 3'UTR (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- FAM162A | c.*1115A>T | 3'UTR (SNP) | VAF 22/176 reads (13%) | called by muse, mutect2, varscan2
- GCSAML | c.*1520A>G | 3'UTR (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- GDI1 | c.*265G>A | 3'UTR (SNP) | VAF 25/45 reads (56%) | catalogued as rs1291369341; called by muse, mutect2, varscan2
- GLCE | chr15:69272210 T>C | 3'Flank (SNP) | VAF 13/41 reads (32%) | called by muse, varscan2
- GNB1 | chr1:1892170 A>C | 5'Flank (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2
- GRAMD2B | c.*697del | 3'UTR (DEL) | VAF 26/117 reads (22%) | called by mutect2, pindel, varscan2
- GSTZ1 | c.474+87A>C | Intron (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2
- IGLL5 | c.-40C>T | 5'UTR (SNP) | VAF 41/153 reads (27%) | catalogued as rs145696836, COSV73251009; called by muse, mutect2, varscan2
- IGSF11 | c.*1704dup | 3'UTR (INS) | VAF 36/70 reads (51%) | catalogued as rs1007426165; called by mutect2, varscan2
- ITGA6 | chr2:172504706 G>A | 3'Flank (SNP) | VAF 66/156 reads (42%) | called by muse, mutect2, varscan2
- KCNH1 | c.*112C>G | 3'UTR (SNP) | VAF 4/93 reads (4%) | called by muse, mutect2
- KLF7 | c.*4230A>C | 3'UTR (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- KLHL40 | c.*53G>A | 3'UTR (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- LILRB2 | c.*149A>G | 3'UTR (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- MCHR1 | c.-459C>T | 5'UTR (SNP) | VAF 50/119 reads (42%) | catalogued as rs191351212; called by muse, mutect2, varscan2
- MDGA1 | c.-123G>A | 5'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- MFSD14B | c.*1270_*1271del | 3'UTR (DEL) | VAF 27/110 reads (25%) | called by pindel, varscan2
- MIPOL1 | c.*2294_*2296del | 3'UTR (DEL) | VAF 38/74 reads (51%) | catalogued as rs1159748657; called by pindel, varscan2
- MIR668 | n.57G>C | RNA (SNP) | VAF 72/163 reads (44%) | called by muse, mutect2, varscan2
- NGLY1 | c.131+76C>T | Intron (SNP) | VAF 30/90 reads (33%) | called by muse, varscan2
- PDE4DIP | c.637-7710C>G | Intron (SNP) | VAF 16/93 reads (17%) | catalogued as rs781790074; called by mutect2, varscan2
- PEG10 | c.*4942G>A | 3'UTR (SNP) | VAF 40/160 reads (25%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*6099C>G | 3'UTR (SNP) | VAF 24/398 reads (6%) | catalogued as rs894521502; called by muse, mutect2
- PPP1R18 | c.-393_-392dup | 5'UTR (INS) | VAF 55/159 reads (35%) | called by mutect2, pindel, varscan2
- PRKRIP1 | c.*948_*949del | 3'UTR (DEL) | VAF 82/178 reads (46%) | called by pindel, varscan2
- PSMC6 | c.247+118T>G | Intron (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.372-541G>A | Intron (SNP) | VAF 3/48 reads (6%) | catalogued as rs949892520; called by muse, mutect2
- RARRES2P7 | n.58C>T | RNA (SNP) | VAF 44/122 reads (36%) | called by muse, mutect2, varscan2
- RND3 | c.*1049T>G | 3'UTR (SNP) | VAF 46/108 reads (43%) | called by muse, mutect2, varscan2
- RNF152 | c.*7008A>G | 3'UTR (SNP) | VAF 47/124 reads (38%) | called by muse, mutect2, varscan2
- SLC16A7 | c.*1531del | 3'UTR (DEL) | VAF 32/90 reads (36%) | called by mutect2, pindel, varscan2
- SLC9A8 | c.*392T>C | 3'UTR (SNP) | VAF 66/177 reads (37%) | called by muse, mutect2, varscan2
- SMARCA4 | c.2617-49C>T | Intron (SNP) | VAF 20/294 reads (7%) | catalogued as rs773510670; called by muse, mutect2
- SNTG2 | c.1489-89A>T | Intron (SNP) | VAF 12/16 reads (75%) | called by muse, mutect2, varscan2
- SYNGR1 | c.*322G>A | 3'UTR (SNP) | VAF 10/187 reads (5%) | called by muse, mutect2
- TMEM170A | c.304+80T>C | Intron (SNP) | VAF 18/20 reads (90%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975304 G>A | 5'Flank (SNP) | VAF 113/125 reads (90%) | catalogued as COSV66081281; called by muse, mutect2, varscan2
- TNFAIP8 | c.*481_*483delinsC | 3'UTR (DEL) | VAF 18/85 reads (21%) | called by pindel, varscan2*
- TPCN2 | c.*505G>A | 3'UTR (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- TPRXL | n.1988G>T | RNA (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- TRAT1 | c.-23A>G | 5'UTR (SNP) | VAF 91/326 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.60941-101T>C | Intron (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- TUBA1C | c.214-13038C>T | Intron (SNP) | VAF 36/100 reads (36%) | catalogued as rs528312487; called by muse, mutect2, varscan2
- VGLL3 | c.*588T>C | 3'UTR (SNP) | VAF 20/164 reads (12%) | called by mutect2, varscan2
- ZBTB10 | c.*6427G>T | 3'UTR (SNP) | VAF 6/156 reads (4%) | called by muse, mutect2
